HCMI case HCM-SANG-1085-C20 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Rectum. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/50854c28-2457-4b22-98a9-50d4b7c66701

Demographics
Sex at birth: male; Days to birth: -25,750 days (70.5 years before the index date).

Diagnoses (1)
1. Mucinous adenocarcinoma: ICD-O-3 morphology code: 8480/3; ICD-10 code: C20; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Rectum, NOS; Classification of tumor: primary; Tumor grade: G3; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Synchronous malignancy: No; Sites of involvement: Peritoneum, NOS; Uicc clinical stage: Stage IIIB; Uicc pathologic m: M0; Uicc pathologic n: N1; Uicc pathologic stage: Stage IIIC; Uicc pathologic t: T4b; Uicc staging system edition: 7th.
   Pathology details: Lymphatic invasion present: No; Perineural invasion present: No; Vascular invasion present: Yes; Vascular invasion type: Extramural.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Treatment intent type: Neoadjuvant.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Neoadjuvant.
   Treatment given: Treatment type: Radiation, 2D Conventional; Treatment intent type: Neoadjuvant.

Follow-up (1 entry)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Peritoneum, NOS; Days to progression: 0 days.

Molecular and laboratory tests
- MLH1 (IHC): Positive.
- MSH2 (IHC): Positive.
- MSH6 (IHC): Positive.
- PMS2 (IHC): Positive.
- Test: Negative; Mismatch repair mutation: Yes.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample HCM-SANG-1085-C20-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
- Sample HCM-SANG-1085-C20-10A-01D-A80T-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
- Sample HCM-SANG-1085-C20-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
